Somatic mutation profile of tumor specimen TCGA-AF-5654-01A (aliquot TCGA-AF-5654-01A-01D-1657-10) from TCGA case TCGA-AF-5654, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 73.2 years (26,738 days).
Specimen TCGA-AF-5654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 631340dc-b8fc-4a76-936e-7c1433f72c27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-5654-10A (Blood Derived Normal), aliquot TCGA-AF-5654-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e0e30a9-30e8-4ae8-9ea5-2d553670b090

The open-access MAF lists 133 somatic variants for this specimen: 99 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 32, Nonsense Mutation 7, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, RNA 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ITGB3 | c.2248C>T p.R750* | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as rs121918450, CM973033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 104/174 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC1 | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749166736, COSV60687702; called by muse, mutect2
- AKAP12 | c.2871C>A p.N957K | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs377313534; called by muse, mutect2, varscan2
- AMY2B | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 16/442 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.191); catalogued as COSV100796346; called by muse, mutect2
- ANK3 | c.11606C>T p.A3869V | Missense Mutation (SNP) | VAF 155/390 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as rs1351085518, COSV55062829; called by muse, mutect2, varscan2
- ANKRD17 | c.3769A>G p.T1257A | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58222363; called by muse, mutect2, varscan2
- APOB | c.11848G>T p.A3950S | Missense Mutation (SNP) | VAF 109/211 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as COSV99266075; called by muse, mutect2, varscan2
- ARHGEF40 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs935991117, COSV53884330; called by muse, mutect2, varscan2
- ARMC4 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs753179587, COSV53462843; called by muse, mutect2, varscan2
- ASB12 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV62857114; called by muse, mutect2, varscan2
- ATP7B | c.3532A>G p.T1178A | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1387431334, CM061649, COSV54439658; called by muse, mutect2, varscan2
- C16orf71 | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV54788601; called by muse, mutect2, varscan2
- CARD11 | c.2062C>T p.R688* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV62754868; called by muse, mutect2, varscan2
- CEP152 | c.4472C>T p.P1491L (on ENST00000380950 / NM_001194998.2; = p.P1435L on NM_014985.4) | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764880513, COSV57856705; called by muse, mutect2, varscan2
- CES5A | c.1604G>A p.R535Q (on ENST00000290567 / NM_001143685.2; = p.R485Q on NM_145024.3) | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV51867376; called by muse, mutect2, varscan2
- CFAP251 | c.1218T>A p.N406K | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV56611445; called by muse, mutect2, varscan2
- CFAP47 | c.2545C>T p.L849F | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs748094553, COSV52886149; called by muse, mutect2, varscan2
- CFAP58 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100866118; called by muse, mutect2, varscan2
- COPZ1 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017662; called by muse, mutect2, varscan2
- CPLX4 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs756554813, COSV55313855; called by muse, mutect2, varscan2
- CPT1A | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs762094475, COSV55758428; called by muse, mutect2, varscan2
- CREB3L3 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV50211734; called by muse, mutect2, varscan2
- CSMD1 | c.10601C>T p.S3534L (on ENST00000520002; = p.S3533L on NM_033225.6) | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs764398530, COSV59336713; called by muse, mutect2, varscan2
- DCHS1 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777899134, COSV55037431; called by muse, varscan2
- DENND5A | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs148317700; called by muse, mutect2, varscan2
- DNER | c.866T>C p.V289A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.185); catalogued as COSV100519269; called by muse, mutect2
- DPYD | c.1543G>A p.V515I | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs148994843; called by muse, mutect2, varscan2
- FAM184A | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58855326; called by muse, mutect2, varscan2
- FAM214A | c.2675A>G p.D892G | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs751865651, COSV55924968; called by muse, mutect2, varscan2
- FAM9A | c.365_373del p.H122_A125delinsP | In Frame Del (DEL) | VAF 139/310 reads (45%) | catalogued as COSV66813393; called by mutect2, pindel, varscan2
- FBXW7 | c.1105G>T p.E369* (on ENST00000281708 / NM_001349798.2; = p.E289* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 109/246 reads (44%) | catalogued as COSV55898045; called by muse, mutect2, varscan2
- FBXW7 | c.572C>G p.S191* (on ENST00000281708 / NM_001349798.2; = p.S111* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 57/209 reads (27%) | catalogued as COSV99656056; called by muse, mutect2, varscan2
- FGL1 | c.390T>A p.S130R | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV67712741; called by muse, mutect2, varscan2
- FLNA | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.56); catalogued as COSV61045030; called by muse, mutect2, varscan2
- GABBR1 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.092); catalogued as rs138809665; called by muse, mutect2, varscan2
- GJA10 | c.222G>T p.L74F | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65355349; called by muse, mutect2, varscan2
- GLIS1 | c.1359G>T p.G453= | Splice Region (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56550157; called by muse, mutect2, varscan2
- GLIS3 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765789414, COSV60928241; called by muse, mutect2, varscan2
- GPX5 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765613212, COSV69079341; called by muse, mutect2, varscan2
- GRIP1 | c.504G>A p.G168= | Splice Region (SNP) | VAF 8/60 reads (13%) | catalogued as COSV54027670; called by muse, mutect2, varscan2
- HERC2 | c.6647G>A p.R2216H | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs763055552, COSV55328512; called by muse, mutect2, varscan2
- HJV | c.479G>A p.R160H (on ENST00000336751 / NM_213653.4; = p.R47H on NM_145277.5) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV60952338; called by muse, mutect2, varscan2
- HMBS | c.637T>C p.Y213H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.966); catalogued as rs1237128803, COSV53828369; called by muse, mutect2, varscan2
- HR | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.113); catalogued as rs753334836, COSV57192828; called by muse, mutect2, varscan2
- IGBP1 | c.1003C>T p.R335* | Nonsense Mutation (SNP) | VAF 52/227 reads (23%) | catalogued as COSV60556561; called by muse, mutect2, varscan2
- IL3RA | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs200665918, COSV58431795; called by muse, mutect2, varscan2
- KCNN3 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55214016; called by muse, mutect2, varscan2
- KCNQ3 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 69/169 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.578); catalogued as COSV66468956, COSV66473047; called by muse, mutect2, varscan2
- KDR | c.2989A>G p.K997E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.194); catalogued as rs764489577, COSV55767544; called by muse, mutect2, varscan2
- KIAA0586 | c.382G>C p.V128L (on ENST00000619416 / NM_001244190.2; = p.V143L on NM_014749.5) | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV54177327; called by muse, mutect2, varscan2
- LRRC37B | c.1942C>G p.Q648E | Missense Mutation (SNP) | VAF 124/342 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV100496311; called by muse, mutect2, varscan2
- LRRIQ3 | c.1337C>A p.A446E | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV63045119; called by muse, mutect2, varscan2
- MAGEC1 | c.2470A>T p.S824C | Missense Mutation (SNP) | VAF 51/101 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as COSV53574773; called by muse, mutect2, varscan2
- MEGF6 | c.3055C>T p.H1019Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.216); catalogued as COSV53891099; called by muse, mutect2, varscan2
- MEGF8 | c.7855G>A p.V2619M (on ENST00000251268 / NM_001271938.2; = p.V2552M on NM_001410.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs772954605, COSV52089070; called by muse, mutect2, varscan2
- MON1B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.026); catalogued as COSV50248280; called by muse, mutect2, varscan2
- MORC3 | c.1450C>T p.R484W | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs763982889, COSV101247744; called by muse, mutect2, varscan2
- MUC16 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV67473101; called by muse, mutect2, varscan2
- MYO7A | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782459520, CM1310654, COSV101289162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NARF | c.1340G>A p.R447H | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1355816578, COSV59112212; called by muse, mutect2, varscan2
- NCOR2 | c.3674A>G p.Y1225C | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1208772467, COSV62299401; called by muse, mutect2, varscan2
- NIP7 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV54741850; called by muse, mutect2, varscan2
- NOS1 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 143/241 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV57614550; called by muse, mutect2, varscan2
- NT5C1A | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756357555, COSV52494964; called by muse, mutect2, varscan2
- OLIG2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60972750; called by muse, mutect2, varscan2
- PAPOLG | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99474814; called by muse, mutect2, varscan2
- PCDHA12 | c.2017G>A p.G673S | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV56513273; called by muse, mutect2, varscan2
- PDCD6IP | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 51/108 reads (47%) | catalogued as rs757821681, COSV56243732; called by muse, mutect2, varscan2
- PDZD8 | c.995+1G>C p.X332_splice | Splice Site (SNP) | VAF 40/100 reads (40%) | catalogued as COSV57826239; called by muse, mutect2, varscan2
- POLA1 | c.2686G>C p.E896Q | Missense Mutation (SNP) | VAF 90/363 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as COSV66887321; called by muse, mutect2, varscan2
- POPDC3 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV54644558; called by muse, mutect2, varscan2
- RANBP3L | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56956191; called by muse, mutect2, varscan2
- RNF128 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as COSV55251900; called by muse, mutect2, varscan2
- RNF180 | c.1068C>A p.D356E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV56960861, COSV99684757; called by muse, mutect2, varscan2
- ROS1 | c.5572C>A p.P1858T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV63856519; called by muse, mutect2, varscan2
- RSPH10B2 | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 194/598 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV51869848; called by muse, varscan2
- SEL1L3 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV53542919; called by muse, mutect2, varscan2
- SLC22A14 | c.488A>G p.D163G | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV56198108; called by muse, mutect2, varscan2
- SMARCA1 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1342799293, COSV64411153; called by muse, mutect2, varscan2
- SNAPC3 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV101072775; called by muse, mutect2, varscan2
- SP7 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as rs752735792, COSV58191119; called by muse, mutect2, varscan2
- SPACA1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as rs373094172, COSV99389783; called by muse, mutect2, varscan2
- SRMS | c.146G>T p.C49F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53921093; called by muse, mutect2, varscan2
- TAF4 | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1198912126, COSV53338583; called by muse, mutect2, varscan2
- TCEAL6 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 104/439 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs782217171, COSV65653883; called by muse, mutect2, varscan2
- TET1 | c.4595G>A p.R1532Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs780172713, COSV65382560; called by muse, mutect2, varscan2
- TMEM64 | c.799A>T p.T267S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.621); catalogued as COSV69127895; called by muse, mutect2, varscan2
- TRIM35 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59522565, COSV59523200; called by muse, mutect2, varscan2
- TRIM43 | c.408C>G p.H136Q | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV55528490, COSV55529145; called by muse, mutect2, varscan2
- TRPS1 | c.2191C>A p.H731N (on ENST00000220888 / NM_001330599.2; = p.H744N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV55246185, COSV99635315; called by muse, mutect2, varscan2
- TTN | c.16154C>A p.A5385E (on ENST00000591111; = p.A4458E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/57 reads (58%) | PolyPhen benign (0.049); catalogued as COSV100617365, COSV60326825; called by muse, mutect2, varscan2
- VAT1L | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV56821803; called by muse, mutect2, varscan2
- WDR33 | c.3991G>A p.G1331S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs763142345, COSV59250487; called by muse, mutect2, varscan2
- ZEB2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs771155056, COSV57959222; called by muse, mutect2, varscan2
- ZMYM2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101243541, COSV67035080; called by muse, mutect2, varscan2
- ZNF430 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.246); catalogued as COSV55110440; called by muse, mutect2, varscan2
- APC | c.4192_4193del p.R1399Ffs*9 | Frame Shift Del (DEL) | VAF 49/94 reads (52%) | called by pindel, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1290C>T p.C430= (on ENST00000611781; = p.C374= on NM_052997.2) | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as rs369621160, COSV64611494; called by muse, varscan2
- AP2A1 | c.1437C>T p.A479= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs368042642; called by muse, mutect2, varscan2
- ATG2A | c.2676G>A p.S892= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs200748453, COSV65967163; called by muse, mutect2, varscan2
- C1QL2 | c.453C>T p.S151= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99733232; called by muse, mutect2, varscan2
- CDH23 | c.3825C>G p.T1275= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV56470363; called by muse, mutect2
- COL6A3 | c.5370G>A p.A1790= | Silent (SNP) | VAF 46/95 reads (48%) | catalogued as rs775654736, COSV55109236; called by muse, mutect2, varscan2
- CRYGB | c.21C>T p.Y7= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs758440322, COSV53680421; called by muse, mutect2, varscan2
- FAM131C | c.744C>T p.P248= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs760727574, COSV65153501; called by muse, mutect2
- FAM47A | c.1674G>A p.P558= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as rs372486528, COSV60493816, COSV60495716; called by muse, mutect2, varscan2
- GCC2 | c.490T>C p.L164= | Silent (SNP) | VAF 73/123 reads (59%) | catalogued as COSV59177163; called by muse, mutect2, varscan2
- HMGCL | c.312A>G p.P104= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as COSV52526346; called by muse, mutect2, varscan2
- HTR5A | c.690C>T p.R230= | Silent (SNP) | VAF 69/120 reads (58%) | catalogued as COSV55284709; called by muse, mutect2, varscan2
- IGSF21 | c.1176C>T p.F392= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs139607566; called by muse, mutect2, varscan2
- KLHL13 | c.885C>T p.Y295= | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs150238128, COSV53249095; called by muse, mutect2, varscan2
- MYH7B | c.5661C>T p.G1887= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs745665276, COSV52680735; called by muse, mutect2, varscan2
- PLPPR5 | c.342G>A p.P114= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs761061098, COSV54174314; called by muse, mutect2, varscan2
- PLXNB2 | c.1698C>T p.R566= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1346661557, COSV100834106; called by muse, mutect2, varscan2
- PNMA2 | c.1089C>T p.D363= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs202002019; called by muse, mutect2, varscan2
- POLG | c.1386G>C p.S462= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV51522405; called by muse, mutect2, varscan2
- PRAMEF19 | c.21C>A p.R7= | Silent (SNP) | VAF 16/72 reads (22%) | called by muse, varscan2
- PRPF31 | c.258C>T p.A86= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs750573765, COSV58084899; called by muse, mutect2, varscan2
- SCN10A | c.4260C>T p.N1420= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV71860513, COSV71861794; called by muse, mutect2, varscan2
- SLC27A1 | c.1050C>T p.R350= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV53099278; called by muse, varscan2
- SPATA31D1 | c.162C>T p.T54= | Silent (SNP) | VAF 136/312 reads (44%) | catalogued as rs775078647, COSV61196969; called by mutect2, varscan2
- SPATA31D1 | c.1215A>T p.S405= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs754837777, COSV61196979; called by muse, mutect2, varscan2
- SYT9 | c.1359C>T p.I453= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs762713738, COSV100608031, COSV59624727; called by muse, mutect2, varscan2
- TCP1 | c.442C>T p.L148= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV58459298; called by muse, mutect2, varscan2
- TMEM132B | c.1968C>A p.T656= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs756925697, COSV54756725; called by muse, mutect2
- WDR25 | c.753C>T p.T251= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100091498, COSV58937425; called by muse, mutect2, varscan2
- WSB2 | c.147C>T p.I49= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs755524304, COSV59574315; called by muse, mutect2, varscan2
- ZNF138 | c.477A>C p.I159= (on ENST00000307355 / NM_001367572.1; = p.I133= on NM_006524.4) | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as COSV56465691; called by muse, mutect2, varscan2
- ZNF808 | c.1173A>G p.R391= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV63120256; called by muse, mutect2, varscan2
- C8orf31 | n.447C>T | RNA (SNP) | VAF 8/27 reads (30%) | catalogued as rs538935958; called by muse, mutect2, varscan2
- DPP6 | c.244-140700C>A | Intron (SNP) | VAF 22/32 reads (69%) | catalogued as COSV59620773; called by muse, varscan2
